Somatic mutation profile of tumor specimen TCGA-90-7767-01A (aliquot TCGA-90-7767-01A-11D-2122-08) from TCGA case TCGA-90-7767, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 56.2 years (20,534 days).
Specimen TCGA-90-7767-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6d3c1e01-ccd3-4f86-9f92-e1ed46d40dbd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-90-7767-10A (Blood Derived Normal), aliquot TCGA-90-7767-10A-01D-2122-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4447fed0-d5a0-4ec1-a021-ad383f182e9f

The open-access MAF lists 126 somatic variants for this specimen: 91 protein-altering or splice-affecting, 31 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 83, Silent 31, Nonsense Mutation 3, RNA 3, Frame Shift Del 2, Intron 1, Frame Shift Ins 1, Splice Site 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 24/48 reads (50%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ACTC1 | c.641T>C p.I214T | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as COSV99291660; called by muse, mutect2, varscan2
- ACTN2 | c.2125G>T p.D709Y | Missense Mutation (SNP) | VAF 87/260 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV100856582; called by muse, mutect2, varscan2
- ADGRF5 | c.1949A>G p.N650S | Missense Mutation (SNP) | VAF 55/110 reads (50%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV51930803, COSV99345064; called by muse, mutect2
- ALOXE3 | c.1632G>T p.Q544H | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100559632; called by muse, mutect2, varscan2
- ALPK3 | c.1747G>T p.G583C | Missense Mutation (SNP) | VAF 37/64 reads (58%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.019); catalogued as COSV99360350; called by muse, mutect2, varscan2
- ARHGAP17 | c.1024G>A p.E342K | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.761); catalogued as COSV99252984; called by muse, mutect2, varscan2
- ASTN2 | c.791C>T p.A264V | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.113); catalogued as COSV100525249; called by muse, mutect2, varscan2
- ASTN2 | c.475G>A p.V159M | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV100525251; called by muse, mutect2, varscan2
- C2orf78 | c.2506C>T p.R836W | Missense Mutation (SNP) | VAF 17/132 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as rs934293521, COSV68516307; called by muse, mutect2, varscan2
- CABS1 | c.1091C>A p.S364Y | Missense Mutation (SNP) | VAF 30/97 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.66); catalogued as COSV56734186, COSV56734591; called by muse, mutect2, varscan2
- CARMIL3 | c.3572G>T p.R1191L | Missense Mutation (SNP) | VAF 25/131 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV100549274, COSV100549339; called by muse, mutect2, varscan2
- CDCP2 | c.872C>T p.P291L | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.788); catalogued as rs778829789, COSV100313353; called by muse, mutect2, varscan2
- CDH10 | c.1249C>A p.P417T | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.301); catalogued as COSV100050367; called by muse, mutect2, varscan2
- CELSR1 | c.695G>T p.R232L | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as COSV99417116; called by muse, mutect2, varscan2
- CFAP54 | c.6525A>G p.I2175M | Missense Mutation (SNP) | VAF 15/25 reads (60%) | SIFT tolerated (0.18); PolyPhen benign (0.022); catalogued as COSV100733000; called by mutect2, varscan2
- CFHR5 | c.460G>C p.A154P | Missense Mutation (SNP) | VAF 56/139 reads (40%) | SIFT tolerated (0.37); PolyPhen benign (0.026); catalogued as COSV99888126; called by muse, mutect2, varscan2
- CLEC12A | c.424G>T p.D142Y | Missense Mutation (SNP) | VAF 40/167 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV100429397; called by muse, mutect2, varscan2
- CSMD1 | c.8948G>C p.G2983A (on ENST00000520002; = p.G2982A on NM_033225.6) | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as COSV100144828, COSV59280097; called by muse, mutect2, varscan2
- CSMD1 | c.7795A>G p.R2599G (on ENST00000520002; = p.R2598G on NM_033225.6) | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.468); catalogued as COSV100144835; called by muse, mutect2, varscan2
- CSTF2T | c.940A>G p.I314V | Missense Mutation (SNP) | VAF 33/81 reads (41%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs931222996, COSV100484095; called by muse, mutect2, varscan2
- CYRIA | c.583C>G p.P195A | Missense Mutation (SNP) | VAF 44/118 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100838245; called by muse, mutect2, varscan2
- DCLK2 | c.1818G>C p.L606F | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV99651529; called by muse, mutect2
- E2F7 | c.1879C>T p.P627S | Missense Mutation (SNP) | VAF 15/85 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.033); catalogued as rs756852278, COSV100523355; called by muse, mutect2, varscan2
- EFHB | c.2174T>C p.I725T | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.462); catalogued as COSV99859219; called by muse, mutect2, varscan2
- FIZ1 | c.1196C>T p.A399V | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs748852809, COSV55607361; called by muse, mutect2, varscan2
- GLG1 | c.1802A>T p.Y601F | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.088); catalogued as COSV99215404; called by muse, mutect2, varscan2
- GOLGA5 | c.1441G>T p.E481* | Nonsense Mutation (SNP) | VAF 23/83 reads (28%) | catalogued as COSV99370762; called by muse, mutect2, varscan2
- HAPLN1 | c.826G>T p.V276L | Missense Mutation (SNP) | VAF 104/190 reads (55%) | SIFT tolerated (0.26); PolyPhen benign (0.062); catalogued as COSV99164648; called by muse, mutect2, varscan2
- HEATR5B | c.3509A>G p.H1170R | Missense Mutation (SNP) | VAF 29/147 reads (20%) | SIFT tolerated (0.59); PolyPhen benign (0.023); catalogued as rs1558751662, COSV99248526, COSV99250149; called by muse, mutect2, varscan2
- HGF | c.1099A>T p.T367S | Missense Mutation (SNP) | VAF 58/129 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99735918; called by muse, mutect2, varscan2
- KATNBL1 | c.275G>A p.S92N | Missense Mutation (SNP) | VAF 63/114 reads (55%) | SIFT tolerated (0.41); PolyPhen benign (0.015); catalogued as COSV99854278; called by muse, mutect2, varscan2
- KCNH6 | c.82A>T p.K28* | Nonsense Mutation (SNP) | VAF 81/261 reads (31%) | catalogued as COSV100120842; called by muse, mutect2, varscan2
- KDM6A | c.2383G>A p.G795R | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.288); catalogued as COSV100937961; called by muse, mutect2, varscan2
- KIAA1109 | c.12055G>C p.D4019H | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.62); catalogued as COSV52680104, COSV99146718; called by muse, mutect2, varscan2
- LCT | c.2727G>T p.W909C | Missense Mutation (SNP) | VAF 50/95 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99928777; called by muse, mutect2, varscan2
- LMBR1 | c.1403A>G p.H468R | Missense Mutation (SNP) | VAF 40/139 reads (29%) | SIFT tolerated (0.68); PolyPhen benign (0.007); catalogued as COSV62222853; called by muse, mutect2, varscan2
- LPO | c.1803C>A p.Y601* | Nonsense Mutation (SNP) | VAF 49/106 reads (46%) | catalogued as COSV99228493; called by muse, mutect2, varscan2
- LRRC4C | c.980G>T p.C327F | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99537236; called by muse, mutect2
- MAGEC1 | c.2989A>T p.N997Y | Missense Mutation (SNP) | VAF 78/116 reads (67%) | SIFT deleterious (0); PolyPhen possibly damaging (0.86); catalogued as COSV99595047; called by muse, mutect2, varscan2
- MRAP | c.124T>C p.F42L | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.043); catalogued as COSV100353212; called by muse, mutect2, varscan2
- MRPL38 | c.121G>T p.D41Y | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.972); catalogued as COSV100504965; called by muse, mutect2, varscan2
- MTRR | c.443G>A p.R148Q (on ENST00000264668; = p.R121Q on NM_002454.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 92/206 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs201913006, COSV52948154; called by muse, mutect2, varscan2
- MYH1 | c.2417A>C p.Q806P | Missense Mutation (SNP) | VAF 39/71 reads (55%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs1469465697, COSV99875122, COSV99877205; called by muse, mutect2, varscan2
- NFE2L2 | c.809C>T p.S270L | Missense Mutation (SNP) | VAF 28/89 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.086); catalogued as rs778033173, COSV101229332; called by muse, mutect2, varscan2
- NLRC4 | c.28G>A p.A10T | Missense Mutation (SNP) | VAF 13/87 reads (15%) | SIFT tolerated (0.56); PolyPhen benign (0.099); catalogued as COSV100707261; called by muse, mutect2, varscan2
- NPEPPS | c.2464C>T p.H822Y | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.034); catalogued as COSV100443477; called by muse, mutect2, varscan2
- NRG3 | c.1184A>T p.Q395L | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.234); catalogued as COSV100930867; called by mutect2, varscan2
- OGDHL | c.992C>A p.S331Y | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100934215; called by muse, mutect2, varscan2
- OLFML1 | c.647C>A p.T216K | Missense Mutation (SNP) | VAF 13/111 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.575); catalogued as COSV100206124; called by muse, mutect2, varscan2
- OR11H4 | c.814C>A p.P272T | Missense Mutation (SNP) | VAF 40/155 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100197412; called by muse, mutect2, varscan2
- OR4X2 | c.689C>T p.S230F | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100183175; called by muse, mutect2, varscan2
- OR6K6 | c.670G>T p.V224F (on ENST00000368144; = p.V200F on NM_001005184.1) | Missense Mutation (SNP) | VAF 39/88 reads (44%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.77); catalogued as COSV100933694; called by muse, mutect2, varscan2
- OR8B3 | c.748C>A p.L250M | Missense Mutation (SNP) | VAF 23/103 reads (22%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.913); catalogued as COSV100660370; called by muse, mutect2, varscan2
- OVOL1 | c.655G>A p.G219S | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779727157, COSV60119523; called by muse, mutect2, varscan2
- PANX3 | c.890G>T p.W297L | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV99421301; called by muse, mutect2, varscan2
- PAPPA2 | c.1876G>T p.G626W | Missense Mutation (SNP) | VAF 29/84 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100866596; called by muse, mutect2, varscan2
- PCDH11X | c.1184G>T p.R395M | Missense Mutation (SNP) | VAF 55/93 reads (59%) | SIFT tolerated (0.07); PolyPhen benign (0.196); catalogued as COSV100009114; called by muse, mutect2, varscan2
- PCDH11X | c.1185G>T p.R395S | Missense Mutation (SNP) | VAF 55/94 reads (59%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.566); catalogued as COSV100009118; called by muse, mutect2, varscan2
- PCDH8 | c.3149C>A p.P1050H | Missense Mutation (SNP) | VAF 40/91 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs1312618094, COSV100131297; called by muse, mutect2, varscan2
- PKHD1L1 | c.7024G>A p.E2342K | Missense Mutation (SNP) | VAF 3/8 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs771453720, COSV65747923; called by muse, mutect2
- PLEKHH2 | c.1337T>C p.V446A | Missense Mutation (SNP) | VAF 37/195 reads (19%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV99174394; called by muse, mutect2, varscan2
- PLEKHM3 | c.1078C>G p.Q360E | Missense Mutation (SNP) | VAF 38/107 reads (36%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV101216326; called by muse, mutect2, varscan2
- PLOD1 | c.1795A>G p.I599V | Missense Mutation (SNP) | VAF 23/46 reads (50%) | SIFT tolerated (1); PolyPhen probably damaging (0.965); catalogued as COSV52144450; called by muse, mutect2, varscan2
- PREP | c.539A>T p.Y180F (on ENST00000369110; = p.Y246F on NM_002726.5) | Missense Mutation (SNP) | VAF 25/99 reads (25%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.666); catalogued as COSV100963753; called by muse, mutect2, varscan2
- RABGAP1L | c.1016G>A p.R339Q | Missense Mutation (SNP) | VAF 49/183 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.166); catalogued as rs1374812072, COSV52286688; called by muse, mutect2, varscan2
- RAD51D | c.345G>A p.Q115= | Splice Region (SNP) | VAF 24/84 reads (29%) | catalogued as rs1555568469, CS116852, COSV100239001; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RP1L1 | c.1707C>A p.S569R | Missense Mutation (SNP) | VAF 36/81 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as COSV101223010; called by muse, mutect2, varscan2
- RUNDC3A | c.458G>A p.R153K | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.011); catalogued as COSV99841727; called by muse, mutect2, varscan2
- SATL1 | c.253A>G p.N85D (on ENST00000395409; = p.N272D on NM_001012980.2) | Missense Mutation (SNP) | VAF 116/170 reads (68%) | SIFT tolerated (0.28); PolyPhen benign (0.262); catalogued as COSV100260690; called by muse, mutect2, varscan2
- SETD3 | c.1288C>T p.L430F | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.881); catalogued as COSV100074882; called by muse, mutect2
- SHTN1 | c.331G>C p.D111H | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.629); catalogued as COSV99598590; called by muse, mutect2, varscan2
- SIGLEC6 | c.1149C>A p.N383K | Missense Mutation (SNP) | VAF 85/145 reads (59%) | SIFT tolerated (0.16); PolyPhen benign (0.031); catalogued as COSV100585199; called by muse, mutect2, varscan2
- SLC26A5 | c.403+1G>T p.X135_splice | Splice Site (SNP) | VAF 12/37 reads (32%) | catalogued as COSV100098770; called by muse, mutect2, varscan2
- SMOX | c.38A>T p.D13V | Missense Mutation (SNP) | VAF 36/138 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); catalogued as COSV99602934; called by muse, mutect2, varscan2
- SPAG6 | c.1234A>T p.T412S | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.04); catalogued as COSV100510020, COSV57624083; called by muse, mutect2, varscan2
- TBC1D32 | c.3515T>C p.I1172T | Missense Mutation (SNP) | VAF 35/83 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs779498885, COSV99249685; called by muse, mutect2, varscan2
- TBC1D4 | c.2113G>A p.A705T | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT tolerated (0.6); PolyPhen benign (0.033); catalogued as rs746805947, COSV100884545; called by muse, mutect2, varscan2
- TFB2M | c.1036G>A p.D346N | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT tolerated (0.4); PolyPhen benign (0.114); catalogued as rs1408608069, COSV100830428; called by muse, mutect2, varscan2
- THBS3 | c.1024G>A p.E342K | Missense Mutation (SNP) | VAF 47/125 reads (38%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.506); catalogued as COSV100857504; called by muse, mutect2, varscan2
- TMPRSS9 | c.1558G>A p.V520I (on ENST00000648592; = p.V486I on NM_182973.2) | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.009); catalogued as rs1198027196, COSV100211099; called by muse, mutect2
- UGT2B11 | c.935T>A p.V312E | Missense Mutation (SNP) | VAF 98/273 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.014); catalogued as COSV101485222; called by muse, mutect2, varscan2
- VPS13C | c.10723A>C p.S3575R (on ENST00000644861 / NM_020821.3; = p.S3532R on NM_017684.5) | Missense Mutation (SNP) | VAF 55/99 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51130504; called by muse, mutect2, varscan2
- WDR81 | c.4010G>A p.R1337H (on ENST00000409644 / NM_001163809.2; = p.R286H on NM_152348.4) | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as rs773481022, COSV58488497; called by muse, varscan2
- ZC3H7B | c.2773G>T p.V925L | Missense Mutation (SNP) | VAF 21/107 reads (20%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.729); catalogued as COSV100687102; called by muse, mutect2, varscan2
- ZNF516 | c.1642G>C p.G548R | Missense Mutation (SNP) | VAF 22/29 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101487220, COSV71587161; called by muse, mutect2, varscan2
- ZNF527 | c.1652A>G p.E551G | Missense Mutation (SNP) | VAF 49/77 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100648695; called by muse, mutect2, varscan2
- ZNF664 | c.749C>A p.T250K | Missense Mutation (SNP) | VAF 25/123 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.92); catalogued as COSV100544399; called by muse, mutect2, varscan2
- FAT2 | c.2445_2448dup p.A817Qfs*33 | Frame Shift Ins (INS) | VAF 22/55 reads (40%) | called by mutect2, pindel, varscan2
- SPEF2 | c.2103del p.D702Mfs*8 | Frame Shift Del (DEL) | VAF 22/102 reads (22%) | called by mutect2, pindel, varscan2
- SUSD2 | c.773del p.A258Efs*20 | Frame Shift Del (DEL) | VAF 8/46 reads (17%) | called by mutect2, pindel, varscan2
- ABI1 | c.675T>C p.S225= | Silent (SNP) | VAF 45/187 reads (24%) | catalogued as COSV100697766; called by muse, mutect2, varscan2
- AGAP4 | c.525C>T p.T175= | Silent (SNP) | VAF 28/76 reads (37%) | catalogued as rs1332685301; called by mutect2, varscan2
- ARID3A | c.1614G>A p.P538= | Silent (SNP) | VAF 79/129 reads (61%) | catalogued as rs201358067, COSV99708279; called by muse, mutect2, varscan2
- CELF2 | c.387G>A p.V129= (on ENST00000416382 / NM_001025077.3; = p.V136= on NM_006561.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 13/55 reads (24%) | catalogued as COSV100256913; called by muse, mutect2, varscan2
- COL24A1 | c.2949A>T p.T983= | Silent (SNP) | VAF 55/102 reads (54%) | catalogued as COSV100993001; called by muse, mutect2, varscan2
- CSMD3 | c.4059C>T p.H1353= (on ENST00000297405 / NM_001363185.1; = p.H1249= on NM_052900.3) | Silent (SNP) | VAF 15/45 reads (33%) | catalogued as COSV99821619; called by muse, mutect2, varscan2
- FKBP8 | c.1233G>A p.R411= (on ENST00000222308 / NM_001308373.2; = p.R412= on NM_012181.5) | Silent (SNP) | VAF 12/16 reads (75%) | catalogued as rs773595163, COSV99723913; called by muse, varscan2
- GJD2 | c.906G>T p.L302= | Silent (SNP) | VAF 21/45 reads (47%) | catalogued as COSV99290593; called by muse, mutect2, varscan2
- GRM1 | c.3015C>A p.A1005= | Silent (SNP) | VAF 54/115 reads (47%) | catalogued as COSV51193474, COSV51205654; called by muse, mutect2, varscan2
- HMCN1 | c.388T>C p.L130= | Silent (SNP) | VAF 21/71 reads (30%) | catalogued as COSV99625243; called by muse, mutect2, varscan2
- KCNH1 | c.30A>G p.L10= | Silent (SNP) | VAF 85/197 reads (43%) | catalogued as COSV99657711; called by muse, mutect2, varscan2
- LTBP3 | c.924C>T p.G308= | Silent (SNP) | VAF 16/47 reads (34%) | catalogued as COSV100099129; called by muse, mutect2, varscan2
- MICAL2 | c.4074G>A p.V1358= | Silent (SNP) | VAF 42/212 reads (20%) | catalogued as rs899913549, COSV99811488; called by muse, varscan2
- MRC1 | c.225G>T p.L75= | Silent (SNP) | VAF 88/238 reads (37%) | catalogued as COSV100509512; called by muse, mutect2, varscan2
- MYLK | c.1971G>T p.L657= | Silent (SNP) | VAF 54/135 reads (40%) | catalogued as COSV100658612; called by muse, mutect2, varscan2
- NCOA3 | c.345G>T p.P115= | Silent (SNP) | VAF 17/39 reads (44%) | catalogued as COSV100507245; called by muse, mutect2, varscan2
- OR10S1 | c.996G>A p.*332= | Silent (SNP) | VAF 13/50 reads (26%) | catalogued as COSV101602436, COSV101602449; called by muse, mutect2, varscan2
- OR6K6 | c.669G>T p.V223= (on ENST00000368144; = p.V199= on NM_001005184.1) | Silent (SNP) | VAF 42/91 reads (46%) | catalogued as COSV100933693; called by muse, mutect2, varscan2
- PCDHB6 | c.2088G>A p.S696= | Silent (SNP) | VAF 49/201 reads (24%) | catalogued as COSV50727495; called by muse, mutect2, varscan2
- PHYH | c.876G>C p.V292= | Silent (SNP) | VAF 22/55 reads (40%) | catalogued as COSV99538051; called by muse, mutect2, varscan2
- SKIV2L | c.672C>T p.D224= | Silent (SNP) | VAF 16/59 reads (27%) | catalogued as rs771283543, COSV100952630; called by muse, mutect2, varscan2
- SPATA25 | c.249G>A p.R83= | Silent (SNP) | VAF 40/253 reads (16%) | catalogued as COSV99509698; called by muse, mutect2, varscan2
- TARS1 | c.1014C>T p.L338= | Silent (SNP) | VAF 50/128 reads (39%) | catalogued as COSV99465560; called by muse, mutect2, varscan2
- TECTA | c.4221C>T p.H1407= | Silent (SNP) | VAF 4/32 reads (13%) | catalogued as COSV99878951; called by muse, varscan2
- TIMD4 | c.612C>T p.T204= | Silent (SNP) | VAF 34/80 reads (43%) | catalogued as COSV50858139; called by muse, mutect2, varscan2
- TMEM132E | c.2397C>A p.I799= (on ENST00000321639; = p.I889= on NM_001304438.2) | Silent (SNP) | VAF 37/99 reads (37%) | catalogued as COSV100395999; called by muse, mutect2, varscan2
- TMEM67 | c.1857G>A p.L619= | Silent (SNP) | VAF 28/112 reads (25%) | catalogued as COSV60046057; called by muse, mutect2, varscan2
- TNNC1 | c.474G>A p.K158= | Silent (SNP) | VAF 11/52 reads (21%) | catalogued as rs770807038, COSV51768823; called by muse, mutect2, varscan2
- TTBK1 | c.2106C>T p.L702= | Silent (SNP) | VAF 43/76 reads (57%) | catalogued as COSV99443923; called by muse, mutect2, varscan2
- UGT2A1 | c.1518C>T p.V506= | Silent (SNP) | VAF 16/104 reads (15%) | catalogued as COSV99683927; called by muse, mutect2, varscan2
- ZSWIM5 | c.3156G>T p.L1052= | Silent (SNP) | VAF 26/53 reads (49%) | catalogued as COSV99869948; called by muse, mutect2, varscan2
- C3P1 | n.3310G>A | RNA (SNP) | VAF 29/46 reads (63%) | called by muse, mutect2, varscan2
- KIR3DX1 | n.726T>C | RNA (SNP) | VAF 32/54 reads (59%) | catalogued as rs780603967, COSV99683021; called by muse, mutect2, varscan2
- MARCHF1 | c.-322-85825C>A | Intron (SNP) | VAF 55/170 reads (32%) | called by muse, mutect2, varscan2
- XIST | n.9805C>A | RNA (SNP) | VAF 23/38 reads (61%) | called by muse, mutect2, varscan2
